Surgical pathology report (de-identified scan), TCGA case TCGA-3N-A9WC, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greenville Health System, specimen TCGA-3N-A9WC-06A (Metastatic).

[page 1 of 2]
PATHOLOGY EXAMINATION

COLLECTED:

CLIENT:

PHYSICIAN:

ADDITIONAL:

COPY TO/NOTES:

NO ADDITIONAL PHYSICIANS

RECEIVED:

REPORTED:

LOCATION:

Page 1 of 2

SPECIMEN(S) RECEIVED:

A: Left axillary node level 1,2 + 3 *stitch marks level 2

B: Level 3 left lymph node (axillary)

C: Rt. shoulder melanoma *short stitch - superior, medial *long stitch - inferior, lateral

D: Rt axillary sentinel node #1

ICD6-3

Melanoma, NOS 8720/3

Site: Lymph node, axilla
C77.3

W11/9/14

CLINICAL DATA/HISTORY:

Two specimens sent for tissue banking.

Patient with history of left upper back melanoma remotely with new regional recurrence in left axilla and separate new right upper back 2.8 mm. primary for wide local excision and sentinel lymph node biopsy and left lymph node dissection level I, II, and III

FINAL PATHOLOGIC DIAGNOSIS:

A. "LEFT AXILLARY NODE LEVEL I, II, III" AND B. "LEVEL III LEFT AXILLARY LYMPH NODE":
• SUMMARY OF ALL LYMPH NODES FOR LEFT AXILLA:

- METASTATIC MALIGNANT MELANOMA TO 1 OF 15 LYMPH NODES (1/15).
- SIZE OF METASTATIC MALIGNANT MELANOMA: 7 CM (GROSS DIMENSION).
- EXTRACAPSULAR EXTENSION: NOT IDENTIFIED.

• DETAIL:

- LEVEL I: METASTATIC MALIGNANT MELANOMA TO 1 OF 5 LEVEL I LYMPH NODES
- LEVEL II: 5 OF LEVEL II LYMPH NODES, NEGATIVE FOR METASTASIS.
- LEVEL III: 5 LEVEL III LYMPH NODES, NEGATIVE FOR METASTASIS.

C. "RIGHT SHOULDER", WIDE LOCAL EXCISION:

- SKIN WITH PRIOR PROCEDURE SITE CHANGES.
- NEGATIVE FOR RESIDUAL MALIGNANT MELANOMA.

D. "RIGHT AXILLARY SENTINEL NODE #1":

- LYMPH NODE, NEGATIVE FOR METASTASIS (0/1).

COMMENT:

Diagnosis discussed

ELECTRONICALLY SIGNED OUT

GROSS DESCRIPTION:

A. Left axillary node level 1,2 + 3 *stitch marks level 2: The specimen is received fresh labeled left axillary node level 1, 2, and 3", and consists of an oriented fragment of fibrofatty tissue measuring 15 x 12 x 4 cm. Near one end is an attached suture designating level 2. Levels 1 and 3 are not indicated. There is a palpably firm mass measuring 7 x 5.5 x 2.5 cm that is indicated by level 1 by Multiple lymph nodes are dissected from all three levels. Three representative portions of the largest (level 1) lymph node are utilized for tissue banking. With the exception of the largest lymph node, the lymph nodes are entirely submitted.

[page 2 of 2]
Summary of sections: A1-A5) Largest mass (level 1, A1 adjacent to tissue utilized for tissue banking). A6) Single level 1 lymph node unsectioned. A7) Single level 1 lymph node bisected. A8) Single level 1 lymph node bisected. A9) Multiple unsectioned level 1 lymph nodes. A10-A12) Multiple unsectioned level 2 lymph nodes. A13) Multiple unsectioned level 3 lymph nodes.

B. Level 3 left lymph node (axillary): Received fresh labeled "L axillary lymph node level 3" and consists of three tan lymph nodes ranging in greatest dimension from 0.2 to 1 cm. The lymph nodes are entirely submitted unsectioned in cassettes B1-B2.

C. Rt. shoulder melanoma "short stitch - superior, medial "long stitch - inferior, lateral: Received in formalin labeled "Right shoulder melanoma", is a 12.0 x 4.4 cm oriented, tan-white skin ellipse which is excised to a depth of 2.7 cm. There is a short stitch designating superior, medial (12 o'clock) and a long stitch designating inferior, lateral (6 o'clock). The epidermis displays a 0.8 x 0.8 cm ill-defined, pink-red lesions which comes to within 1.3 cm of the nearest 3 o'clock margin. The specimen is inked black from 12 o'clock to 3 o'clock to 6 o'clock, blue from 6 o'clock to 9 o'clock to 12 o'clock, and the 12 o'clock margin is inked yellow. The specimen is sectioned and representative sections are submitted as follows: C1-C6 center, transverse sections to include entire lesion (C1 and C2 are contiguous sections, C3 and C4 are contiguous sections, C5 and C6 are contiguous sections), C7 radial sections of the 6 o'clock and yellow inked 12 o'clock apices.

D. Rt axillary sentinel node #1: Received in formalin labeled "Right axillary sentinel node #1", is a 1.5 x 0.7 x 0.5 cm ovoid, pink-tan candidate lymph node which is bisected to reveal a pink-tan, smooth cut surface. The specimen is submitted in its entirety in D1.

MICROSCOPIC DESCRIPTION:

A. The largest mass (A1 - A4) represents an apparent lymph node largely replaced by metastatic malignant melanoma. Extracapsular spread is not definitively identified. Panmelanoma immunoperoxidase stains are performed on blocks A6 - A13. Tissue pick up is focally noted and knife carry-over is seen. Background staining is also seen. No additional metastatic foci are present.

B. Panmelanoma immunoperoxidase stains are performed on both tissue blocks. Metastatic melanoma is not apparent.

C. Prior biopsy site changes are noted. Residual malignant melanoma is not identified.

D. Lymph node profiles are evident. A Panmelanoma immunoperoxidase stain is performed and is negative for metastasis.

Source: NCI Genomic Data Commons file af6f3517-06ca-48b2-86fb-f12257cf9626 (TCGA-3N-A9WC.DF472314-0643-473F-9233-EC77505148C7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).